Gene-level copy-number profile of tumor specimen TCGA-55-6982-01A from TCGA case TCGA-55-6982, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB.
Specimen TCGA-55-6982-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.1a5e33e6-2949-47ea-91ee-944611025ed4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-6982-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ceb74f8c-5e88-436d-87f5-ecfb37e9d86c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 58; copy number 1: 2,245; copy number 2: 21,288; copy number 3: 7,443; copy number 4: 20,847; copy number 5: 5,248; copy number 6: 2,002; copy number 7: 146; copy number 8: 10; copy number 9: 44; copy number 10: 42; copy number 13: 39; copy number 14: 9; copy number 15: 43; copy number 16: 19; copy number 17: 13; copy number 18: 47; copy number 19: 33; copy number 23: 51; copy number 24: 2; copy number 27: 8; copy number 31: 124; copy number 32: 54; copy number 35: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-6982-01A-11D-1943-01): tumor purity 0.25, ploidy 2.61, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 58 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:19,233,366–24,178,263, 35 genes (within-gene range 0–4): HSPD1P15, CDH18, AC093303.1, AC094103.1, CDH18-AS1, LINC02146, LINC02241, AC138938.1, AC140168.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1, C5orf17, AC026784.1, ADH5P5, Y_RNA.
- chr18:50,560,087–52,339,025, 23 genes (within-gene range 0–1): MAPK4, AC012433.2, AC012433.1, MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3, AC016383.3, AC016383.2, AC016383.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 533 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–9,045,940, 186 genes, copy number 10–35 (broad region; genes not listed).
- chr5:9,053,816–9,053,895, 1 gene, copy number 19: MIR4636.
- chr5:9,546,200–10,249,897, 19 genes, copy number 16 (within-gene range 3–16): SNHG18, SNORD123, AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221, AC091905.2, AC091905.3, AC091905.1, AC091905.4, AC034229.1, AC034229.6, AC034229.5, AC034229.2, AC034229.3, AC034229.4, ATPSCKMT.
- chr5:10,971,836–11,904,446, 1 gene, copy number 18 (within-gene range 3–18): CTNND2.
- chr5:12,794,100–18,746,173, 100 genes, copy number 18–32 (broad region; genes not listed).
- chr5:28,548,135–28,809,291, 3 genes, copy number 31 (within-gene range 4–31): AC008825.1, AC109472.1, RNU6-909P.
- chr5:30,733,557–32,604,079, 39 genes, copy number 10 (within-gene range 4–10): AC026433.1, RPL19P11, AC026421.1, AC113386.1, CDH6, DUX4L51, DROSHA, Y_RNA, C5orf22, AC022417.1, RNU6-363P, PDZD2, AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6, RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279, AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579, AC074134.1, SUB1.
- chr5:43,511,058–43,707,405, 8 genes, copy number 27: C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12.
- chr5:52,853,183–52,889,954, 2 genes, copy number 24: AC022133.2, B3GNTL1P1.
- chr12:56,663,341–56,688,408, 1 gene, copy number 9 (within-gene range 2–9): PTGES3.
- chr12:56,712,305–58,244,865, 84 genes, copy number 9–31 (broad region; genes not listed).
- chr12:66,950,754–71,118,247, 89 genes, copy number 14–31 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,995. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
